Surgical pathology report (de-identified scan), TCGA case TCGA-IW-A3M4, project TCGA-SARC (Sarcoma), tissue source site Cedars Sinai, specimen TCGA-IW-A3M4-01A (Primary Tumor).

[page 1 of 7]
Ordering M D

Pathologist:
Assistant:
Date of Procedure:
Date Received:

Copies To:

SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Breast profile results

SPECIMEN(S) SUBMITTED: A. PERI CERVICAL TUMOR, B. PERI URETERAL TUMOR, C. UTERUS, D. PERI URETHRAL MASS, E. ROUND LIGAMENT, F. OMENTUM #1, G. OMENTUM #2, H. OMENTUM #3, I. RIGHT PELVIC PERITONEUM, J. RIGHT GUTTER, K. LEFT GUTTER, L. LEFT RETROPERITONEUM, M. LEFT PELVIC LYMPH NODE, N. RIGHT PELVIC LYMPH NODE, O. RIGHT COMMON ILLIAC LYMPH NODE, P. PERIAORTIC LYMPH NODE RIGHT

DIAGNOSIS:

A. SOFT TISSUE, PERICERVICAL "TUMOR" BIOPSY:

- Secondary involvement by leiomyosarcoma (see comment)

B. SOFT TISSUE, PERIURETERAL, "TUMOR" BIOPSY:

- Metastatic leiomyosarcoma (see comment)

C. UTERUS, AND SEGMENTS OF LEFT FALLOPIAN TUBE, TOTAL ABDOMINAL HYSTERECTOMY AND PARTIAL LEFT SALPINGECTOMY:

- Primary uterine leiomyosarcoma, with some epithelioid features and associated necrosis (see comment)
- Tumor measures about 9 x 7.5 x 7.5 cm and occupies the right lateral uterine wall, extends into parametrial soft tissues and into the adjacent right broad ligament
- No unequivocal lymphatic or blood vessel invasion by tumor identified
- Cervix is free of tumor
- Tiny to small detached tumor fragments noted in one section from left parametria (slide C27), probably representing strays rather than metastasis
- One small smooth muscle neoplasm showing marked (diffuse) cellular atypia, probably representing intrauterine spread of leiomyosarcoma
- Another small uterine smooth muscle tumor with atypia of uncertain significance
- One small cellular leiomyoma with moderately increased cellularity peripherally and paucicellular partially hyalinized central area
- Seven "usual" leiomyomas, one of which is present in the lower uterine segment
- Endometrium with proliferative features
- Benign endometrial polyps, posterior lower uterine segment
- Serosal/subserosal lymphovascular ectasia
- Focal subserosal endosalpingiosis
- Para uterine mesothelial cysts
- Cervix with focal mucosal erosion, acute and chronic inflammation, reactive squamous atypia, parakeratosis, reserve (basal cell) hyperplasia, squamous metaplasia, endocervical tunnel clusters, nabothian cysts, and a benign endocervical polyp
- Uterine serosal adhesions

1CD-0-3

Local

leiomyosarcoma, Nos 8890/3

Site uterus, Nos C55-9

Page 1 of 7

PATIENT NOTIFIED OF RESULTS		
DR:	NURSE:	DATE:

EW
12/20/11

[page 2 of 7]
******* Addendum - Please See End of Report *******

- Short proximal segment of left fallopian tube with mild chronic inflammation, vascular ectasia, and paratubal Walthard rests
- D. SOFT TISSUE, PERIURETHRAL, "MASS" EXCISION:**
- Metastatic leiomyosarcoma (see comment)
- E. SOFT TISSUE, ROUND LIGAMENT, LATERALITY NOT SPECIFIED, EXCISION:**
- Metastatic/secondary leiomyosarcoma (see comment)
- F. OMENTUM "#1", PARTIAL OMENTECTOMY:**
- Adhesions, mild chronic inflammation, and focal reactive mesothelial proliferation
- No evidence of metastatic tumor
- G. OMENTUM, "#2", PARTIAL OMENTECTOMY:**
- Adhesions
- No evidence of metastatic tumor
- H. OMENTUM, "#3", PARTIAL OMENTECTOMY:**
- Adhesions, chronic inflammation and reactive mesothelial proliferation
- No evidence of metastatic tumor
- I. SOFT TISSUE, RIGHT PELVIC PERITONEUM, BIOPSY:**
- Cautery artifacts
- No evidence of metastatic tumor
- J. SOFT TISSUE, RIGHT GUTTER, BIOPSY:**
- No evidence of metastatic tumor
- K. SOFT TISSUE, LEFT GUTTER, BIOPSY:**
- No evidence of metastatic tumor
- L. SOFT TISSUE, LEFT RETROPERITONEUM, BIOPSY:**
- No evidence of metastatic tumor
- M. LYMPH NODES, LEFT PELVIC, EXCISION:**
- Six reactive lymph nodes
- No evidence of metastatic tumor (0/6)
- N. LYMPH NODES, RIGHT PELVIC, EXCISION:**
- Four reactive lymph nodes
- No evidence of metastatic tumor (0/4)
- O. LYMPH NODE, RIGHT COMMON ILIAC, EXCISION:**
- One reactive lymph node
- No evidence of metastatic tumor (0/1)
- P. LYMPH NODES, RIGHT PERIAORTIC, EXCISION:**
- Three reactive lymph nodes
- No evidence of metastatic tumor (0/3)

COMMENT: Preliminary pathologic findings were reported to the office of Dr. [redacted] on [redacted] and subsequently discussed with Dr. [redacted]. A battery of immunohistochemical stains was subsequently performed. The tumor cells exhibit strong positive staining for vimentin and smooth muscle-specific actin. Many of the neoplastic cells also stain positively for desmin and some also stain positively for CD10. No specific staining of the neoplastic cells for myoD1, CD117,

[page 3 of 7]
***** Addendum - Please See End of Report *****

keratin AE1/AE3 or S-100 protein is detected. Results of immunohistochemical stains for estrogen and progesterone receptors will be reported in an addendum.

HISTORY: Symptomatic fibroid

MICROSCOPIC: See diagnosis.

SPECIAL STUDIES: Additional H&E (C27x1)

IMMUNOSTAINS: On sections from block C13, including SMA, MyoD1, vimentin, keratin AE1/AE3, CD10, CD117, S-100, and desmin; ER (C14); PR (c14)

GROSS:

A. PERICERVICAL TUMOR

Labeled with the patient's name, labeled "pericervical tumor", and received in formalin is a 1.5 x 1.5 x 0.3 cm aggregate of several irregularly shaped fragments of soft tan tumor and scant blood clot.

Entirely submitted.

A1. Multiple

B. PERIURETERAL TUMOR

Labeled with the patient's name, labeled "periureteral tumor", and received in formalin is a 1.5 x 1.0 x 0.3 cm aggregate of several irregularly shaped fragments of soft tan friable tissue and scant blood clot.

Entirely submitted.

B1. 2

C. UTERUS

Labeled with the patient's name, labeled "uterus", and received fresh in the Operating Room for intraoperative frozen section, is a 510 gram total hysterectomy specimen with an attached segment of left fallopian tube. The uterus is asymmetric and markedly distorted in shape due to the presence of underlying mass lesions (see below). The uterus measures about 12.0 cm from the fundus to the ectocervix, 10.0 cm from cornu to cornu, and up to 9.0 cm from the anterior surface to the posterior surface. The uterine serosa is pink-tan, and shows some adhesions and some attached thin-walled translucent clear to pale yellow fluid-filled cysts, the latter of which measure up to about 1.0 cm in diameter. The cystic lesions are present in the anterior fundic region. Attached to the uterus, there are parametrial (parauterine and paracervical) soft tissues that measure up to about 1.5 cm in width on the right side and up to about 1.0 cm in width on the left side. The right parametrial tissues are invaded by semisoft, tan tumor. The left parametrial tissues are focally hemorrhagic but appear grossly free of tumor. The cervix is about 4.0 cm long and has a maximum diameter of 5.0 cm in the ectocervical region. The mucosa lining the ectocervix is tan to pink-tan and shows a few tiny punctate areas of hemorrhage, but is otherwise grossly unremarkable. No vaginal cuff is identified. The paracervical and parametrial tissues anteriorly are inked blue and those posteriorly are inked black. The external cervical os is slit-shaped, about 0.8 cm in diameter and patent. The uterus was previously incised on both sides at the time of intraoperative consultation. The cervical transformation zone is distinct. The endocervical canal is about 3.0 cm long. In the anterior endocervical near the lower uterine segment, there is a 0.5 cm in diameter semisoft tan endocervical polyp. Cut sections of the cervix, including the polyp reveal several mucus-filled cyst, ranging from less than 0.1 to about 0.6 cm in diameter. The cervix appears grossly free of tumor. The endometrial cavity is about 6.0 cm long and up to 1.5 cm in width. Within the posterior lower uterine segment, there is about a 0.5 cm diameter semisoft tan endometrial polyp. Elsewhere the endometrium is relatively smooth, tan to red-tan and ranges from less than 0.1 to about 0.2 cm in thickness. The endometrium appears grossly free of tumor. There is a fairly well-circumscribed 9 x 7.5 x 7.5 cm tumor mass with focally irregular borders that occupies nearly the full thickness of the muscular uterine wall and extends into the adjacent parametrial soft tissues and broad ligament on the right side. The tumor is composed of semisoft tan tissue. No grossly evident areas of necrosis are seen in the large tumor mass; however there are small foci of hemorrhage within the lesion. The intrauterine portion

[page 4 of 7]
***** Addendum - Please See End of Report *****

of the neoplasm involves the fundus and corpus. No extension into the lower uterine segment or cervix is seen. Within the uterus, there are also ten well-circumscribed myomatous masses that range from about 0.2 to 3.0 cm in maximum dimensions. Two of the myomatous lesions are subserosal and the rest are intramural. Nine of the ten myomatous masses are composed of firm tan-white solid tissue without grossly evident areas of hemorrhage or necrosis. One of the myomatous lesions is composed of somewhat softer tan solid tissue without grossly evident areas of hemorrhage or necrosis. Attached to the left cornu of the uterus, there is an 11.5 cm long, up to 0.5 cm diameter fimbriated left fallopian tube. The serosal surface of the fallopian tube is pink-tan, mildly congested, but smooth. Cross sections of the fallopian tube reveal a patent lumen that ranges from pinpoint to about 0.2 cm in diameter. The left fallopian tube appears grossly free of tumor. No left ovarian tissue or right adnexal tissues are identified in the specimen. Several representative sections of the large uterine mass were frozen and sectioned for intraoperative diagnosis (FS #1). Frozen section interpretation was rendered by Dr. . The frozen section remnants and the rest of the specimen are subsequently fixed in formalin.

Representative sections are submitted.

- C1. Remnants of frozen section #1 - 3
- C2. Anterior cervix - 1
- C3. Upper anterior endocervix with polyp - 1
- C4. Posterior cervix - 1
- C5. Upper posterior endocervix - 1
- C6. Anterior uterine fundus - 1
- C7. Anterior uterine corpus - 2
- C8. Anterior lower uterine segment - 2
- C9. Posterior uterine fundus - 2
- C10. Posterior uterine corpus with tiny leiomyoma - 1
- C11. Posterior lower uterine segment with small endometrial polyp - 1
- C12. Uterine tumor extending in close proximity to parametrial tissues - 1
- C13. Uterine tumor in relation to serosa - 1
- C14. Deep aspect of uterine tumor - 1
- C15. Left fallopian tube (proximal, mid and distal segments) - 3
- C16. One intramural leiomyoma - 2
- C17. Five intramural myomatous masses - 5
- C18. One intramural leiomyoma - 1
- C19. Largest subserosal leiomyoma - 3
- C20. Small subserosal leiomyoma - 1
- C21. Anterior uterine fundus with adhesions and parauterine cysts - 2
- C22. Serosa and subserosal myometrium of anterior uterine fundus - 2
- C23-C25. Right parauterine (parametrial and paracervical) soft tissues with tumor - 2 each
- C26. Left parametrial tissues - 2
- C27. Left parametrial tissue - 1

D. PERIURETHRAL MASS

Labeled with the patient's name, labeled "periurethral mass", and received in formalin is a 3.0 x 2.0 x 1.5 cm aggregate of semisoft pink-tan tissue. Representative sections are submitted.

D1. 2

E. ROUND LIGAMENT

Labeled with the patient's name, labeled "round ligament", and received in formalin is a 2.0 x 2.0 x 1.0 cm aggregate of soft pink-tan tissue. Representative sections are submitted.

E1. 4

F. OMENTUM #1

Labeled with the patient's name, labeled "omentum #1", and received in formalin is an 11.0 x 6.5 x 1.5 cm portion of yellow fatty omental tissue showing a few adhesions, but no grossly evident tumor. Representative sections are submitted.

[page 5 of 7]
***** Addendum - Please See End of Report *****

F1. 3

G. OMENTUM #2

Labeled with the patient's name, labeled "omentum #2", and received in formalin is a 12.0 x 10.0 x 1.0 cm piece of yellow fatty omental tissue showing some adhesions, but no grossly evident tumor. Representative sections are submitted.

G1. 3

H. OMENTUM #3

Labeled with the patient's name, labeled "omentum #3", and received in formalin is a 20.0 x 5.0 x 1.5 cm portion of yellow fatty omental tissue showing a few adhesions, but no grossly evident tumor. Representative sections are submitted.

H1. 3

I. RIGHT PELVIC PERITONEUM

Labeled with the patient's name, labeled "right pelvic peritoneum", and received in formalin is a 0.5 x 0.4 x 0.4 cm portion of pink-white hemorrhagic soft tissue.

Entirely submitted.

I1. 1

J. RIGHT GUTTER

Labeled with the patient's name, labeled "right gutter", and received in formalin is a 1.0 x 0.5 x 0.4 cm portion of tan-pink soft tissue.

Entirely submitted.

J1. 1

K. LEFT GUTTER

Labeled with the patient's name, labeled "left gutter", and received in formalin and is a 0.8 x 0.5 x 0.4 cm portion of tan-yellow soft tissue.

Entirely submitted.

K1. 1

L. LEFT RETROPERITONEUM

Labeled with the patient's name, labeled "left peritoneum", and received in formalin is a 0.5 x 0.5 x 0.5 cm portion of red-tan hemorrhagic soft tissue.

Entirely submitted.

L1. 1

M. LEFT PELVIC LYMPH NODE

Labeled with the patient's name, labeled "left pelvic lymph node", and received in formalin is a 3.5 x 2.0 x 1.0 cm portion of focally hemorrhagic soft tan-yellow fibroadipose tissue within which there are embedded several soft tan lymph nodes ranging from about 0.2 to 1.3 cm in maximum dimension.

Entirely submitted.

M1. Multiple lymph nodes and perinodal fibroadipose tissue - 1

N. RIGHT PELVIC LYMPH NODE

Labeled with the patient's name, labeled "right pelvic lymph node" and received in formalin is a 3 x 1.5 x 0.8 cm aggregate of yellow adipose tissue within which there are embedded four soft tan lymph nodes ranging from about 0.2 to 1.4 cm in maximum dimension.

Entirely submitted.

N1. Largest lymph node, bisected - 2

N2. Smaller lymph nodes and perinodal fat - 1

[page 6 of 7]
******* Addendum - Please See End of Report *******

O. RIGHT COMMON ILIAC LYMPH NODE

Labeled with the patient's name, labeled "right common iliac lymph node", and received in formalin is a 3.5 x 1.5 x 0.8 cm portion of lobulated yellow fat within which there is embedded a single semifirm 2.0 x 1.0 x 0.6 cm lymph node. The lymph node is entirely embedded along with some of the perinodal fat.

O1. Single bisected lymph node - 2

P. PERIAORTIC LYMPH NODE RIGHT

Labeled with the patient's name, labeled "periaortic lymph node right", and received in formalin is a 3.8 x 2.0 x 1.0 cm portion of yellow-tan fibroadipose tissue within which there are embedded three semifirm tan lymph nodes measuring about 0.2, 1.5 and 2.5 cm in maximum dimensions.

Entirely submitted.

P1. Largest lymph node, bisected - 2

P2. Two lymph nodes, larger bisected - 2

Gross dictated by

OPERATIVE CALL

OPERATIVE CONSULT (GROSS):

SPECIMEN C, UTERUS/BROAD LIGAMENT MASS:

- Friable, cystic solid 9 cm mass

SPECIMEN C, UTERUS/(FS 1) BROAD LIGAMENT MASS FS:

- Spindle cell neoplasm with foci of early infarction; defer to permanent for definitive characterization

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.
Electronically signed

*****ADDENDUM (****

BLOCK: C14

	TEST RESULT
ESTROGEN RECEPTORS	Positive
PROGESTERONE RECEPTORS	Positive

TEST RESULTS ANTIBODY

ESTROGEN

PROGESTERONE

[page 7 of 7]
***** Addendum - Please See End of Report *****

%Tumor Staining	90%	95%
Staining Intensity	2+~3+	3+

Note: The intensity of nuclear immunohistochemical staining for receptors is graded from 0 for negative; 1+ weak; 2+ moderate; 3+ strong.

DETAILS OF IMMUNOHISTOCHEMISTRY

Paraffin sections were reacted with monoclonal antibodies to:

✓	Estrogen receptors
✓	Progesterone receptors

Note: ER, PR Stains are analyzed using the computer assisted

I, the pathologist of record on the above addendum, personally examined the material described in the addendum, interpreted the results, reviewed this amended report and signed it electronically.

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.
Electronically signed

Source: NCI Genomic Data Commons file c8735f30-140a-4418-a8f0-ba8c7a32a009 (TCGA-IW-A3M4.E8F9A7D9-A374-4B34-A484-B64FF4E6BAFE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).